Somatic mutation profile of tumor specimen TCGA-FY-A3R6-01A (aliquot TCGA-FY-A3R6-01A-11D-A21Z-08) from TCGA case TCGA-FY-A3R6, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 57.5 years (21,009 days).
Specimen TCGA-FY-A3R6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 287d2777-c6bb-47f9-9e18-895ac57b4a3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FY-A3R6-10A (Blood Derived Normal), aliquot TCGA-FY-A3R6-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58ea0ca4-715e-4c74-9d00-d37c6d2b23f6

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS6 | c.1117G>A p.G373S | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66865875; called by mutect2, varscan2
- C11orf87 | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs187108020, COSV59356856; called by muse, mutect2
- CARD10 | c.2606C>T p.S869F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52660863; called by muse, mutect2, varscan2
- EPB41L3 | c.3130G>A p.D1044N | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59471224; called by muse, mutect2, varscan2
- LETM1 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57105041; called by muse, mutect2, varscan2
- SIRT4 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.087); catalogued as rs1303583748, COSV52542072; called by muse, mutect2
- FAT2 | c.5172G>A p.S1724= | Silent (SNP) | VAF 35/216 reads (16%) | catalogued as rs763383764, COSV55831807; called by muse, mutect2, varscan2
- GLYCTK | c.1278G>C p.L426= | Silent (SNP) | VAF 39/149 reads (26%) | catalogued as COSV59794987; called by muse, mutect2, varscan2
- KRTAP10-7 | c.732T>G p.S244= | Silent (SNP) | VAF 59/326 reads (18%) | catalogued as COSV59114019; called by muse, mutect2, varscan2
